Somatic mutation profile of tumor specimen MP2PRT-PATBML-TMP1-A (aliquot MP2PRT-PATBML-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PATBML, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,497 days).
Specimen MP2PRT-PATBML-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c48ce7c-c0f0-4a92-be00-14e465c11caa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATBML-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATBML-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/152c4898-5372-4baf-9760-b026107582be

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, In Frame Ins 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BPIFA1 | c.340del p.Q114Sfs*24 | Frame Shift Del (DEL) | VAF 122/304 reads (40%) | catalogued as COSV62824051; called by mutect2, pindel, varscan2
- KLHL1 | c.680G>C p.R227T | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64773527, COSV64774116; called by muse, mutect2
- PPP1R3A | c.2899C>T p.P967S | Missense Mutation (SNP) | VAF 144/312 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV52878387; called by muse, mutect2, varscan2
- TEK | c.2224G>A p.G742R | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs141520692; called by muse, mutect2
- TLR9 | c.2575C>T p.R859W | Missense Mutation (SNP) | VAF 162/398 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs749912438, COSV62345495; called by muse, mutect2, varscan2
- ZNF425 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 189/463 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV65201432; called by muse, mutect2, varscan2
- IGHV1-69 | c.350_351insTAAGAA p.R117delinsSKK | In Frame Ins (INS) | VAF 37/52 reads (71%) | called by pindel, varscan2
- IGKV1OR2-108 | chr2:113406872 TCACAGTGTT>G | Silent (DEL) | VAF 75/88 reads (85%) | called by pindel, varscan2*
- NR2C2AP | c.*397C>G | 3'UTR (SNP) | VAF 124/309 reads (40%) | called by muse, mutect2, varscan2
